Surgical pathology report (de-identified scan), TCGA case TCGA-24-1471, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1471-01A (Primary Tumor).

[page 1 of 4]
24/1471

DIAGNOSIS:

OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- OVARY, HIGH GRADE SEROUS CARCINOMA WITH PARENCHYMAL AND SURFACE INVOLVEMENT
- OVARIAN SEROUS CARCINOMA DIRECTLY EXTENDS TO UTERINE SEROSA AND SUBJACENT MYOMETRIUM, MESOCOLON, AND RECTOSIGMOID SEROSA
- LYMPHOVASCULAR SPACE INVASION PRESENT
- LEFT FALLOPIAN TUBE, NEGATIVE FOR MALIGNANCY
- SEE SYNOPSIS REPORT AND COMMENT

OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- OVARY, HIGH GRADE SEROUS CARCINOMA, MAINLY SURFACE WITH FOCAL PARENCHYMAL INVOLVEMENT
- FALLOPIAN TUBE, HIGH GRADE SEROUS CARCINOMA, PARATUBAL SOFT TISSUE INVOLVEMENT ONLY

UTERUS, TOTAL ABDOMINAL HYSTERECTOMY

- WEAKLY PROLIFERATIVE ENDOMETRIUM
- LEIOMYOMAS
- SEROSA AND EXTERNAL MYOMETRIUM INVOLVED BY HIGH GRADE SEROUS CARCINOMA
- LOWER UTERINE SEGMENT WITH LYMPHOVASCULAR INVASION BY HIGH GRADE SEROUS CARCINOMA
- CERVIX, CHRONIC INFLAMMATION, NO EVIDENCE OF MALIGNANCY

LARGE INTESTINE, RECTOSIGMOID, EXCISION

- SEROSA, HIGH GRADE SEROUS CARCINOMA
- LARGE INTESTINE MUCOSA AND MUSCULARIS PROPRIA WITH NO EVIDENCE OF MALIGNANCY
- RECTOSIGMOID COLON MARGIN WITH HIGH GRADE SEROUS CARCINOMA IN SEROSA (SEE COMMENT)
- MESOCOLONIC LYMPH NODES, METASTATIC SEROUS CARCINOMA IN FOUR OF TWELVE LYMPH NODES (4/12)

OMENTUM, NODULE, EXCISION (INCLUDING FS1)

- HIGH GRADE SEROUS CARCINOMA, MEASURING 1.6 CM

OMENTUM, EXCISION

- HIGH GRADE SEROUS CARCINOMA, MULTIPLE IMPLANTS, MEASURING UP TO 1.9 CM

LARGE INTESTINE, ANASTOMOTIC DONUT, EXCISION

[page 2 of 4]
[REDACTED]

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'uterus, cervix, bilateral salpingo-oophorectomy, and rectosigmoid,' consisting of colon, measuring 24 x 5 cm, uterus measuring 8.5 x 4.5 x 4 cm, and detached right adnexa, measuring 4.5 x 4 x 1.5 cm. Soft tissue surfaces are inked blue. The colon is opened to show unremarkable tan mucosa. The uterus is opened to show a tan-red polypoid lesion, measuring 1 x 1 cm. Posterior to the uterus and anterior to colon is a heterogeneous tan-red-yellow solid mass, measuring 8.5 x 6.5 x 5.5 cm. The mesentery fat shows a malignant-appearing lymph node, measuring 3 x 2.5 x 2.5 cm. Tumor taken for [REDACTED] Remainder for permanents," by [REDACTED]

[REDACTED]

FS1: Omental nodule, biopsy

- "Poorly differentiated adenocarcinoma, favor Mullerian," by [REDACTED]

[REDACTED]

Microscopic Description and Comment:

Serosal tumor is present at the margin of the rectosigmoid specimen. As the specimen was not oriented, it cannot be determined whether this is the proximal or distal margin. The mucosal surface is free of malignancy.

[REDACTED]

History:

The patient is a [REDACTED] with a pelvic mass. Operative procedure: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, sigmoidectomy, and omentectomy.

Specimen(s) Received:

A: OMENTAL NODULE
B: UTERUS, CERVIX, BILATERAL TUBES AND OVARIES, RECTAL SIGMOID
C: OMENTUM
D: DONUT, INTESTINAL

Gross Description:

The specimens are received in four formalin-filled containers each labeled [REDACTED]. The first container is labeled "omental nodule, FS1/X." It holds a white cassette that holds a piece of yellow-tan fibrofatty tissue, measuring 1.5 x 1.0 x 0.2 cm. There is an ill-defined, white density in the central portion of this piece of tissue. Labeled A1 (FS1). The remainder of the contents of the jar are yellow fibroadipose tissue aggregating to 4.5 x 3 x 2.5 cm with a firm, white-tan, 1.5 x 1.4 x 1 cm nodule attached. Labeled A2 - nodule; A3 - remainder of tissue. Jar 0.

The second container is labeled "uterus, cervix, BSO, rectosigmoid." It holds a previously opened segment of colon with en bloc uterus, and soft tissue mass intervening between the left posterior uterus, and the rectus. The intestine has been previously opened to show a segment of mucosa that has normally folded tan-brown surface. The margins

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

are not oriented. The lumen of the bowel is strictured to an apparent diameter of less than 1 cm at its closest approach to an underlying 8.5 x 6.5 x 5.5 cm soft tissue mass. At the same location, there is an adjacent satellite nodule, possibly representing a metastatic lymph node, measuring 2 x 2 x 3 cm. The tumor itself shows variegated yellow-white extensively necrotic tissue. The soft tissue margins surrounding it have been previously inked. The tumor lies extensively within 2 mm of the margin. It is densely adherent to the left posterior uterine wall. Sections through this area show a putative necrotic cystic ovarian remnant that measures 2.5 x 2 x 2.5 cm. This structure contains abundant necrotic friable pink-tan material. The tumor abuts, but does not definitively infiltrate the underlying myometrium. The uterus has been previously opened to show a convoluted endometrial cavity, and endocervical canal, distorted by multiple underlying firm, white leiomyomas with solid, whorled cut sections. The largest measures 2 cm in greatest dimension. The ectocervix is tan-brown to white, smooth, and unremarkable. The serosal surface is unremarkable except for the left posterior portion, which was adhered to the aforementioned necrotic tumor. The mesenteric adipose tissue is dissected to show twelve lymph nodes in addition to the large metastatic lymph node, previously described. The separately submitted right ovary measures 2.5 x 2 x 1.5 cm, and has an attached brown-purple ovary, measuring 6.5 cm in length and 0.5 cm in diameter. Sections of ovary show a firm, chalky white-yellow parenchyma without cyst. The surface is cerebriform, yellow, and without papillary excrescences. The sections of fallopian tube show tan-brown fallopian tube wall with pinpoint lumen, and no gross tumor. Labeled B1 - colonic margin; B2 and B3 - colon with nearest approach to tumor; B4 to B6 - tumor with nearest soft tissue margin; B7 to B9 - tumor in area of putative residual left ovary; B10 - section adjacent to B8 and B9 (endometrium); B11 - anterior cervix; B12 - posterior cervix; B13 - posterior lower uterine segment with adjacent tumor; B14 - anterior lower uterine segment; B15 - additional posterior lower uterine segment; B16 - anterior endomyometrium with leiomyoma; B17 - posterior endomyometrium with leiomyoma; B18 and B19 - right ovary and fallopian tube; B20 - four putative endometriosis, and four lymph nodes; B21 - four putative lymph nodes; B22 - four putative lymph nodes; B23 - largest lymph node (1). Jar 4.

The third container is labeled "omentum." It holds seven pieces of yellow-brown, fibrofatty tissue, ranging from 2 cm to 11 cm in greatest dimension. Sections of omentum show enumerable firm, white tumor implants, ranging from less than 1 cm to 2 cm in greatest dimension. Labeled C1 to C4 - multiple omental metastasis. Jar 3.

The fourth container is labeled "donuts (intestinal)." It holds two donut-shaped pieces of tan-brown mucosa, measuring 1.5 x 1 x 1.0 cm, and 2 x 1.5 x 1 cm. The mucosa in each piece is invested with numerous metal staples. Labeled D1 - unstapled mucosa. Jar 1.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The location of the primary tumor is the left ovary only

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor does not invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the omentum is present

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIc)

REGIONAL LYMPH NODES (N)

The regional lymph nodes are classified as regional lymph node metastasis (N1)

The total number of regional lymph nodes examined is 12

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

The total number of metastatically-involved lymph nodes is 4
Extranodal extension by tumor metastases is absent

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/N1/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

END OF REPORT

Page 4 of 4

Source: NCI Genomic Data Commons file de68991a-27d3-4ab2-9df9-0a4a252b834b (TCGA-24-1471.D20B8ED1-C74E-4EE8-9AE2-5512429810BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).